Somatic mutation profile of tumor specimen MP2PRT-PANTAG-TMP1-A (aliquot MP2PRT-PANTAG-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANTAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen MP2PRT-PANTAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5225dcbc-f313-4341-98e7-b157c10df843.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANTAG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANTAG-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/790cd83e-e8a4-4fb7-b0cf-26813bbc0e54

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Frame Shift Ins 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 151/509 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs587781371, CD136796, COSV52684761, COSV53551526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHAL6B | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs774239896, COSV55682946; called by muse, mutect2, varscan2
- LTBP2 | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs771852388, COSV99999887; called by muse, mutect2, varscan2
- NOTUM | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs199698572, COSV68826618; called by muse, mutect2, varscan2
- NPFFR2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 176/595 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.446); catalogued as rs1428841227, COSV100440510; called by muse, mutect2, varscan2
- PARD6G | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs750146147, COSV62061154; called by muse, mutect2, varscan2
- SOX9 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 98/665 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV99818725; called by muse, mutect2, varscan2
- CASKIN1 | c.4196C>T p.P1399L | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- CLCN5 | c.212T>G p.L71* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- CYP1B1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 71/914 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2
- KIF4A | c.2520G>C p.K840N | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXD3 | c.350_351insGCCCGGG p.Q118Pfs*47 | Frame Shift Ins (INS) | VAF 171/433 reads (39%) | called by mutect2, pindel, varscan2
- SEMA4F | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 204/489 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD2 | c.5398_5399insAG p.I1800Kfs*3 | Frame Shift Ins (INS) | VAF 54/160 reads (34%) | called by pindel, varscan2
- SFI1 | c.3221dup p.T1075Dfs*35 (on ENST00000400288 / NM_001007467.3; = p.T1044Dfs*35 on NM_014775.4) | Frame Shift Ins (INS) | VAF 293/831 reads (35%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4144A>G p.T1382A (on ENST00000367255 / NM_182961.4; = p.T1389A on NM_033071.3) | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNHD1 | c.12063C>T p.S4021= | Silent (SNP) | VAF 143/522 reads (27%) | called by muse, varscan2
